CPTAC case C3L-07035 — Pancreas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/818a0a41-43a3-4d60-a6cc-79a025752f7a

Demographics
Sex at birth: male; Year of birth: 1951.

Other clinical attributes
- Weight: 79.7 kg; Height: 174 cm; BMI: 26.32.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (1 sample)
- Sample C3L-07035-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 130 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
